Somatic mutation profile of tumor specimen 2e700669-85b0-43fa-a9c7-3eaf5a (aliquot 2e700669-85b0-43fa-a9c7-3eaf5a_D6) from CPTAC case 11BR049, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.8 years (16,729 days).
Specimen 2e700669-85b0-43fa-a9c7-3eaf5a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73607479-fc20-4c80-8fa2-87e053119a53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ad85fadf-31b7-44f3-b6ea-73c55d (Blood Derived Normal), aliquot ad85fadf-31b7-44f3-b6ea-73c55d_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/098221c2-9423-41e2-82e2-c0139ed40cf6

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, RNA 3, 3'Flank 2, 3'UTR 2, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs376430770; called by muse, mutect2, varscan2
- ANKRD30A | c.4061T>C p.I1354T (on ENST00000611781; = p.I1298T on NM_052997.2) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1191233486; called by muse, mutect2, varscan2
- ATP8B2 | c.2462G>A p.R821Q (on ENST00000672630; = p.R788Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1307644549, COSV59246089, COSV59247728; called by muse, mutect2
- DEPDC5 | c.3460G>A p.G1154S (on ENST00000400246; = p.G1223S on NM_014662.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746114133, COSV99836875; called by muse, mutect2, varscan2
- ESRRG | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as rs765878912; called by muse, mutect2, varscan2
- MSI2 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 103/393 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99403629; called by muse, mutect2, varscan2
- SHCBP1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1215040098; called by muse, mutect2, varscan2
- ZNF251 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs374154554; called by muse, mutect2
- ABCA13 | c.3086A>G p.Y1029C | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AKAP3 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 75/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNGA2 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DMXL2 | c.8471C>T p.A2824V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EXT1 | c.906dup p.D303Rfs*11 | Frame Shift Ins (INS) | VAF 211/702 reads (30%) | called by mutect2, pindel, varscan2
- FAM186A | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- GATA2 | c.38A>T p.H13L | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IRS2 | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); called by muse, varscan2
- NEB | c.12372G>T p.W4124C | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PREPL | c.1118T>C p.V373A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- STK33 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- TLE3 | c.2180_2190del p.W727Lfs*9 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by mutect2, pindel, varscan2
- TRAF6 | c.1270T>G p.W424G | Missense Mutation (SNP) | VAF 152/629 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRA2 | c.1014C>T p.S338= | Silent (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- CCDC141 | c.6C>T p.S2= | Silent (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- CNDP1 | c.1062C>T p.G354= | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as rs201741966; called by muse, mutect2, varscan2
- FAM83G | c.2037G>A p.A679= | Silent (SNP) | VAF 59/282 reads (21%) | catalogued as rs571835978, COSV58754967, COSV58758608; called by muse, mutect2, varscan2
- AC068587.8 | n.139G>T | RNA (SNP) | VAF 22/246 reads (9%) | catalogued as rs1435038417; called by muse, mutect2
- AP1B1 | c.*8G>A | 3'UTR (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- CCDC18 | chr1:93278518 G>A | 3'Flank (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- HERC2P2 | n.1800A>G | RNA (SNP) | VAF 47/395 reads (12%) | catalogued as rs562008549; called by muse, mutect2
- MIR6511A2 | chr16:16325390 C>T | 3'Flank (SNP) | VAF 28/60 reads (47%) | catalogued as rs1206706755; called by mutect2, varscan2
- NBR2 | n.1427A>G | RNA (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- PRRG3 | c.*4327T>A | 3'UTR (SNP) | VAF 71/278 reads (26%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+65G>A | Intron (SNP) | VAF 47/180 reads (26%) | catalogued as rs758488970, COSV56493381; called by muse, mutect2, varscan2
